Somatic mutation profile of tumor specimen TCGA-G4-6588-01A (aliquot TCGA-G4-6588-01A-11D-1771-10) from TCGA case TCGA-G4-6588, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIA; Age at diagnosis: 59.0 years (21,532 days).
Specimen TCGA-G4-6588-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9423f4b5-ca89-42c5-a3b7-bacead38ee0d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G4-6588-10A (Blood Derived Normal), aliquot TCGA-G4-6588-10A-01D-1771-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd4e36df-5f29-4969-808b-9405434fd260

The open-access MAF lists 2,483 somatic variants for this specimen: 1,862 protein-altering or splice-affecting, 571 silent, 50 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,304, Silent 571, Frame Shift Del 351, Frame Shift Ins 79, Nonsense Mutation 68, Splice Site 29, Intron 24, In Frame Del 17, RNA 13, Splice Region 9, 5'Flank 5, Translation Start Site 3.

Variants (750 of 2,483; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAT1 | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 52/158 reads (33%) | catalogued as rs532190594, CM102337, COSV54921272; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ALX4 | c.503del p.P168Lfs*13 | Frame Shift Del (DEL) | VAF 18/134 reads (13%) | catalogued as rs876657391, CD144657; ClinVar: pathogenic; called by pindel, varscan2
- AR | c.2105T>A p.L702H | Missense Mutation (SNP) | VAF 39/119 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs864622007, COSV65953052; ClinVar: likely pathogenic; called by muse, varscan2
- ATM | c.8432del p.K2811Sfs*46 | Frame Shift Del (DEL) | VAF 38/108 reads (35%) | catalogued as rs587782558; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRCA2 | c.2957dup p.N986Kfs*2 | Frame Shift Ins (INS) | VAF 23/80 reads (29%) | catalogued as rs80359365; ClinVar: pathogenic; called by mutect2, varscan2
- CEP41 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 65/306 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140259402, CM120755; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CYBB | c.868C>T p.R290* | Nonsense Mutation (SNP) | VAF 51/231 reads (22%) | catalogued as rs886039337, CM960447, COSV66085637; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CYP1B1 | c.868dup p.R290Pfs*37 | Frame Shift Ins (INS) | VAF 34/150 reads (23%) | catalogued as rs587778875; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- DYSF | c.4200dup p.I1401Hfs*8 | Frame Shift Ins (INS) | VAF 38/130 reads (29%) | catalogued as rs398123786; ClinVar: pathogenic; called by mutect2, varscan2
- FGF17 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398123025, CM133820, COSV63925638; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 25/81 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.214); catalogued as CM1313529, CM950459, CX143910, COSV60644274, COSV60648669; called by muse, mutect2, varscan2
- FLNB | c.1592del p.G531Dfs*42 | Frame Shift Del (DEL) | VAF 12/96 reads (13%) | catalogued as rs746105983; ClinVar: pathogenic; called by pindel, varscan2
- HPS1 | c.972del p.M325Wfs*6 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs281865082, CD982691; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- INSL3 | c.217C>T p.R73* | Nonsense Mutation (SNP) | VAF 24/63 reads (38%) | catalogued as rs398122886, CM002796, COSV57953395; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNQ2 | c.868G>A p.G290S | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1057516098, CM135159, COSV60435371; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MEN1 | c.1561del p.R521Gfs*43 | Frame Shift Del (DEL) | VAF 11/48 reads (23%) | catalogued as rs767319284, CD972318, CM080439, COSV53644931; ClinVar: pathogenic; called by pindel, varscan2
- MPL | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763568293, CM055993, COSV65244793; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NUP93 | c.1537+1G>A p.X513_splice | Splice Site (SNP) | VAF 24/78 reads (31%) | catalogued as rs138909849, CS164255; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 15/50 reads (30%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by mutect2, pindel
- PTEN | c.830C>T p.T277I | Missense Mutation (SNP) | VAF 46/166 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.332); catalogued as rs398123329, CM109589, CM151668, COSV64291992, COSV64300125; ClinVar: uncertain significance; called by muse, varscan2
- SPG7 | c.1032del p.G345Afs*87 (on ENST00000268704; = p.G352Afs*87 on NM_003119.4) | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | catalogued as rs760818649; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TBX5 | c.1158del p.S387Afs*7 | Frame Shift Del (DEL) | VAF 13/43 reads (30%) | catalogued as rs1064795870; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- TGFBR2 | c.1583G>A p.R528H | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104893815, CM050762, CM159806, COSV55442586, COSV55450248; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1384C>T p.Q462* (on ENST00000373993 / NM_138932.2; = p.Q454* on NM_014576.4) | Nonsense Mutation (SNP) | VAF 41/125 reads (33%) | catalogued as COSV99255691; called by muse, mutect2, varscan2
- A2M | c.2183C>T p.T728M | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs777702464, COSV59386026; called by muse, varscan2
- ABCA10 | c.180G>T p.K60N | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.158); catalogued as COSV52224202; called by muse, mutect2, varscan2
- ABCA13 | c.12265G>A p.A4089T | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.486); catalogued as COSV71290186; called by muse, mutect2, varscan2
- ABCB1 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs199551851, COSV55945290, COSV55947749; called by muse, mutect2, varscan2
- ABCC8 | c.997G>A p.V333I | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as rs776764243, COSV56847968; called by muse, mutect2, varscan2
- ABCC9 | c.4424C>A p.A1475E | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53975527; called by muse, mutect2, varscan2
- ABCD1 | c.790A>G p.K264E | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as COSV99497420; called by muse, mutect2, varscan2
- ABCD4 | c.1631A>G p.Y544C | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100084178; called by muse, mutect2, varscan2
- ABL1 | c.1129G>A p.V377M | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1368236620, COSV59333881; called by muse, mutect2, varscan2
- ABTB2 | c.1546A>G p.N516D | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.997); catalogued as COSV54390443; called by muse, mutect2, varscan2
- AC018630.4 | c.316C>T p.R106* | Nonsense Mutation (SNP) | VAF 59/176 reads (34%) | catalogued as rs200314617, COSV57392333; called by muse, mutect2, varscan2
- AC023055.1 | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 65/186 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.835); catalogued as rs1337088839, COSV60243588; called by muse, mutect2, varscan2
- AC127029.3 | c.775A>G p.K259E | Missense Mutation (SNP) | VAF 220/652 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as COSV60111244; called by muse, mutect2, varscan2
- ACADVL | c.709T>C p.C237R | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.971); catalogued as rs1189763523, COSV50036679; called by muse, mutect2, varscan2
- ACAT1 | c.1220A>G p.Y407C | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV56188033; called by muse, mutect2, varscan2
- ACKR3 | c.841C>T p.H281Y | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.699); catalogued as COSV56022329; called by muse, mutect2, varscan2
- ACP4 | c.326T>C p.F109S | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as COSV54517305; called by muse, mutect2, varscan2
- ACSL1 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs762658676, COSV55663671; called by muse, varscan2
- ACSM2B | c.1334G>T p.G445V | Missense Mutation (SNP) | VAF 84/393 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100312524, COSV100312563; called by muse, mutect2, varscan2
- ACSM4 | c.1711G>A p.V571I | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs756126335, COSV68067222; called by muse, mutect2, varscan2
- ACTN4 | c.912+1G>A p.X304_splice | Splice Site (SNP) | VAF 20/119 reads (17%) | catalogued as COSV53147258; called by muse, mutect2, varscan2
- ACTR1B | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 19/80 reads (24%) | catalogued as COSV56704745; called by muse, mutect2, varscan2
- ACVR2B | c.1019T>A p.F340Y | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61702631; called by muse, mutect2, varscan2
- ADAM17 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1204442125, COSV60398055; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAM2 | c.642+1G>A p.X214_splice | Splice Site (SNP) | VAF 57/215 reads (27%) | catalogued as COSV99697109; called by muse, mutect2, varscan2
- ADAM21 | c.866A>G p.Q289R | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99960772; called by muse, mutect2, varscan2
- ADAM28 | c.224del p.N75Tfs*53 | Frame Shift Del (DEL) | VAF 48/168 reads (29%) | catalogued as rs570442888; called by mutect2, varscan2
- ADAM30 | c.2018G>A p.G673E | Missense Mutation (SNP) | VAF 51/152 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101023811; called by muse, mutect2, varscan2
- ADAM8 | c.1727C>T p.T576I | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.26); catalogued as COSV69864821; called by muse, mutect2, varscan2
- ADAM8 | c.1559G>A p.G520E | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1292461321, COSV69864827; called by muse, mutect2, varscan2
- ADAM9 | c.220G>T p.G74* | Nonsense Mutation (SNP) | VAF 41/145 reads (28%) | catalogued as COSV65960722; called by muse, mutect2, varscan2
- ADAMTS13 | c.2743C>A p.L915M | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV63021823; called by muse, mutect2, varscan2
- ADAMTS16 | c.2371G>A p.A791T | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as COSV56993812, COSV57006207; called by muse, mutect2, varscan2
- ADAMTS16 | c.3298A>G p.K1100E | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as COSV99940758; called by muse, mutect2, varscan2
- ADAMTS2 | c.1629G>T p.K543N | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV51084085; called by muse, mutect2, varscan2
- ADAMTS5 | c.1490G>A p.C497Y | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759694630, COSV53180239; called by muse, mutect2, varscan2
- ADAMTS6 | c.3130C>T p.Q1044* | Nonsense Mutation (SNP) | VAF 28/86 reads (33%) | catalogued as COSV58683500; called by muse, varscan2
- ADAMTS9 | c.5228A>G p.K1743R | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.019); catalogued as rs1241489495, COSV99899157; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2024A>G p.Q675R | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV54453705; called by muse, mutect2, varscan2
- ADAR | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs755166511, COSV52717151; called by muse, mutect2, varscan2
- ADCY3 | c.801C>A p.N267K | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.152); catalogued as COSV53168802; called by muse, mutect2, varscan2
- ADCY5 | c.1793G>A p.G598D | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59199425; called by muse, mutect2, varscan2
- ADCY6 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV57166022; called by muse, mutect2, varscan2
- ADD3 | c.368C>A p.P123H | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as COSV53323211; called by muse, mutect2, varscan2
- ADGRD1 | c.827A>G p.Y276C | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV55448420; called by muse, mutect2, varscan2
- ADGRE5 | c.2116T>C p.C706R (on ENST00000242786 / NM_078481.4; = p.C613R on NM_001784.5) | Missense Mutation (SNP) | VAF 52/189 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV54392117; called by muse, mutect2
- ADGRF1 | c.1904T>C p.L635S | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51946037; called by muse, mutect2, varscan2
- ADGRG2 | c.1630A>C p.T544P (on ENST00000379869 / NM_001079858.3; = p.T541P on NM_005756.4) | Missense Mutation (SNP) | VAF 66/186 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV100492115; called by muse, mutect2, varscan2
- ADGRL1 | c.4330C>T p.R1444W (on ENST00000340736 / NM_001008701.3; = p.R1439W on NM_014921.5) | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs754657629, COSV61565209; called by muse, mutect2, varscan2
- ADGRL1 | c.1774C>T p.R592W (on ENST00000340736 / NM_001008701.3; = p.R587W on NM_014921.5) | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs868060611, COSV61563640; called by muse, mutect2, varscan2
- ADGRL2 | c.1734G>T p.Q578H | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV54672958; called by muse, mutect2, varscan2
- ADGRV1 | c.17687A>G p.Y5896C | Missense Mutation (SNP) | VAF 78/256 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs1198791918, COSV67987893; called by muse, mutect2, varscan2
- ADK | c.44T>C p.V15A | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV54209198; called by muse, mutect2, varscan2
- ADM | c.530dup p.S178Efs*19 | Frame Shift Ins (INS) | VAF 10/34 reads (29%) | catalogued as rs773405081; called by mutect2, varscan2
- AFAP1L1 | c.833G>T p.R278L | Missense Mutation (SNP) | VAF 74/246 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57045908, COSV57049172; called by muse, mutect2, varscan2
- AFF3 | c.3328A>G p.S1110G | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs1201436769, COSV100418501; called by muse, mutect2
- AGBL1 | c.2570T>C p.L857P | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1242689121, COSV66861688; called by muse, mutect2
- AGMAT | c.429G>T p.E143D | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as COSV101011788, COSV65435957; called by muse, mutect2, varscan2
- AGO2 | c.1289C>T p.P430L | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as COSV55048697; called by muse, mutect2, varscan2
- AGO3 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 60/194 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs754906872, COSV55791941; called by muse, mutect2, varscan2
- AKAP12 | c.2494G>A p.G832R | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.97); catalogued as COSV53576949; called by muse, mutect2, varscan2
- AKAP9 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.057); catalogued as COSV62349441; called by muse, mutect2, varscan2
- AKR1C1 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 84/558 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1554769997, COSV101080424; called by muse, varscan2
- ALDH1B1 | c.52C>A p.R18S | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV66620078; called by muse, mutect2, varscan2
- ALDH3B1 | c.34C>T p.R12W | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1157585732, COSV99141780; called by muse, mutect2, varscan2
- ALG13 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 110/362 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52640444; called by muse, mutect2, varscan2
- ALG2 | c.676T>A p.F226I | Missense Mutation (SNP) | VAF 52/181 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV53060033; called by muse, mutect2, varscan2
- ALMS1 | c.4937C>T p.A1646V | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs1265154676, COSV52512665; called by muse, mutect2, varscan2
- ALPK2 | c.2519C>T p.T840M | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1390793752, COSV64492138; called by muse, mutect2, varscan2
- ALPK2 | c.1568del p.K523Rfs*15 | Frame Shift Del (DEL) | VAF 83/159 reads (52%) | catalogued as rs1341338515; called by mutect2, pindel, varscan2
- ALPK2 | c.1067del p.L356Yfs*2 | Frame Shift Del (DEL) | VAF 37/130 reads (28%) | catalogued as rs756508755; called by mutect2, varscan2
- ALPL | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.387); catalogued as rs753550135, COSV66379351; called by muse, mutect2, varscan2
- ALS2 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 54/216 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs770370996, COSV51888483; called by muse, mutect2, varscan2
- AMDHD2 | c.179del p.G60Afs*68 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | catalogued as COSV53551855; called by mutect2, pindel
- AMOTL1 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.204); catalogued as COSV54416489; called by muse, mutect2, varscan2
- ANGPT4 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.104); catalogued as rs543557667, COSV67921944; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.6203G>A p.S2068N | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV51850533; called by muse, mutect2, varscan2
- ANKMY2 | c.883-1G>C p.X295_splice | Splice Site (SNP) | VAF 32/110 reads (29%) | catalogued as COSV61011974; called by muse, mutect2, varscan2
- ANKRD24 | c.2905C>T p.R969C | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs867343383, COSV53671969; called by muse, mutect2, varscan2
- ANKRD26 | c.4355del p.K1452Rfs*7 | Frame Shift Del (DEL) | VAF 114/461 reads (25%) | catalogued as rs1410888689; called by mutect2, pindel, varscan2
- ANKRD26 | c.1612G>T p.G538W | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.963); catalogued as COSV65776204; called by muse, mutect2, varscan2
- ANKRD55 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 16/187 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.476); catalogued as COSV61947596; called by muse, mutect2
- ANKS4B | c.947C>T p.A316V | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV61139409; called by muse, mutect2, varscan2
- ANPEP | c.1975G>A p.A659T | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV55592394; called by muse, mutect2, varscan2
- ANPEP | c.1337T>C p.V446A | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.196); catalogued as COSV55592407; called by muse, mutect2, varscan2
- AOC1 | c.2222del p.P741Lfs*54 | Frame Shift Del (DEL) | VAF 17/88 reads (19%) | catalogued as rs999461756; called by mutect2, pindel, varscan2
- APOA5 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV57062401; called by muse, mutect2, varscan2
- APOBR | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.316); catalogued as COSV60491483; called by muse, mutect2, varscan2
- APP | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.061); catalogued as rs980390804, COSV61000010; called by muse, mutect2, varscan2
- APPL2 | c.1727T>C p.V576A | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as COSV51591303; called by muse, mutect2, varscan2
- APPL2 | c.633T>A p.F211L | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs766770728, COSV51591248; called by muse, mutect2, varscan2
- AQP2 | c.619G>A p.G207R | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52229740; called by muse, mutect2, varscan2
- AR | c.279G>T p.E93D | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as COSV101017887; called by muse, mutect2, varscan2
- ARAP3 | c.405del p.P136Lfs*14 | Frame Shift Del (DEL) | VAF 11/52 reads (21%) | catalogued as COSV53349371; called by mutect2, pindel, varscan2
- ARFGEF2 | c.4179G>T p.E1393D | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.831); catalogued as COSV64213016; called by muse, mutect2, varscan2
- ARHGAP10 | c.1651G>A p.A551T | Missense Mutation (SNP) | VAF 24/232 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs145234400; called by muse, mutect2
- ARHGAP12 | c.1387-2A>G p.X463_splice | Splice Site (SNP) | VAF 87/289 reads (30%) | catalogued as rs765342639, COSV60964241; called by muse, mutect2, varscan2
- ARHGAP18 | c.32T>C p.V11A | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV63764799; called by muse, mutect2
- ARHGAP27 | c.1939C>T p.R647* (on ENST00000428638 / NM_001282290.1; = p.R306* on NM_199282.3) | Nonsense Mutation (SNP) | VAF 34/93 reads (37%) | catalogued as rs900072522, COSV65357748; called by muse, mutect2, varscan2
- ARHGAP27 | c.1182del p.G395Afs*24 (on ENST00000428638 / NM_001282290.1; = p.G54Afs*24 on NM_199282.3) | Frame Shift Del (DEL) | VAF 38/138 reads (28%) | catalogued as rs1567704517; called by mutect2, pindel, varscan2
- ARHGAP32 | c.1155G>A p.V385= (on ENST00000310343 / NM_001378025.1; = p.V36= on NM_014715.4) | Splice Region (SNP) | VAF 10/43 reads (23%) | catalogued as COSV59850057; called by muse, mutect2, varscan2
- ARHGAP35 | c.4063C>T p.H1355Y | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1447446490, COSV68332567; called by muse, mutect2, varscan2
- ARHGEF19 | c.279del p.M94Cfs*67 | Frame Shift Del (DEL) | VAF 32/100 reads (32%) | catalogued as rs780583014; called by mutect2, pindel, varscan2
- ARHGEF5 | c.3662G>A p.R1221H | Missense Mutation (SNP) | VAF 58/408 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775008156, COSV99282712; called by mutect2, varscan2
- ARHGEF7 | c.1606C>T p.L536F (on ENST00000375741 / NM_001113511.2; = p.L358F on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV54545289; called by muse, varscan2
- ARID1A | c.5069C>A p.T1690N | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV61380266; called by muse, mutect2, varscan2
- ARID1B | c.5887G>T p.G1963W | Missense Mutation (SNP) | VAF 63/182 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51661612, COSV51666752; called by muse, mutect2, varscan2
- ARL10 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as COSV53799149; called by muse, mutect2, varscan2
- ARMC3 | c.1493A>C p.K498T | Missense Mutation (SNP) | VAF 68/207 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.224); catalogued as COSV53063087; called by muse, mutect2, varscan2
- ARMH4 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 52/162 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.235); catalogued as rs201316933; called by muse, mutect2, varscan2
- ARSG | c.754G>A p.V252M | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs756266983, COSV101477884; called by muse, mutect2
- ASAP1 | c.3104C>T p.A1035V | Missense Mutation (SNP) | VAF 115/346 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs1564913877, COSV63050178; called by muse, mutect2, varscan2
- ASB18 | c.1378G>T p.E460* | Nonsense Mutation (SNP) | VAF 16/115 reads (14%) | catalogued as COSV58234489, COSV58235413; called by muse, mutect2, varscan2
- ASB3 | c.338C>T p.T113M | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs540542893, COSV55076063; called by muse, mutect2, varscan2
- ASH2L | c.1286A>G p.E429G | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as COSV51700109; called by muse, mutect2, varscan2
- ASIC2 | c.197A>G p.Y66C | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs201229528, COSV63319688; called by muse, mutect2, varscan2
- ASMTL | c.764G>A p.S255N | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.17); catalogued as COSV67244082; called by muse, varscan2
- ASMTL | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67244093; called by muse, mutect2, varscan2
- ASPM | c.10177T>C p.S3393P | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs200083138, COSV54132164; called by muse, mutect2, varscan2
- ASPM | c.4655A>T p.K1552I | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV54132184; called by muse, mutect2, varscan2
- ASPRV1 | c.304G>A p.V102I | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs149847323; called by muse, mutect2, varscan2
- ASTL | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as rs146799484; called by muse, mutect2, varscan2
- ASTN2 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.236); catalogued as rs1410415075, COSV57767247; called by muse, mutect2, varscan2
- ASXL2 | c.3899G>A p.S1300N | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV55460739; called by muse, mutect2, varscan2
- ATAD5 | c.1115T>C p.V372A | Missense Mutation (SNP) | VAF 19/193 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58975711; called by muse, mutect2
- ATG10 | c.265G>C p.A89P | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.446); catalogued as COSV56427487; called by muse, mutect2, varscan2
- ATG2B | c.2654A>G p.H885R | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.991); catalogued as COSV100737876; called by muse, mutect2, varscan2
- ATG4B | c.966C>A p.F322L | Missense Mutation (SNP) | VAF 68/250 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.088); catalogued as COSV60351501; called by muse, mutect2, varscan2
- ATM | c.7289A>G p.H2430R | Missense Mutation (SNP) | VAF 59/186 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.021); catalogued as rs786202856, COSV53751204; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP10D | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.579); catalogued as COSV56705711, COSV56708838; called by muse, mutect2, varscan2
- ATP11C | c.2286A>G p.I762M | Missense Mutation (SNP) | VAF 83/235 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.962); catalogued as COSV59566696; called by muse, mutect2, varscan2
- ATP1A3 | c.1660C>T p.R554C (on ENST00000545399 / NM_001256214.2; = p.R541C on NM_152296.5) | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1555862292, COSV57488436; called by muse, mutect2, varscan2
- ATP2B4 | c.1979C>T p.T660I | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as COSV58179322; called by muse, mutect2, varscan2
- ATP6V0B | c.349-1G>T p.X117_splice | Splice Site (SNP) | VAF 58/199 reads (29%) | catalogued as COSV99356385; called by muse, mutect2, varscan2
- ATP7A | c.1611A>G p.I537M | Missense Mutation (SNP) | VAF 56/194 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV58448075; called by muse, mutect2, varscan2
- ATRX | c.3490G>A p.D1164N | Missense Mutation (SNP) | VAF 107/345 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.738); catalogued as COSV100971028, COSV64878299; called by muse, mutect2, varscan2
- ATXN7L3 | c.869C>T p.T290M (on ENST00000389384 / NM_001382309.1; = p.T297M on NM_001382308.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.201); catalogued as rs55884059, COSV60229086, COSV60229718; called by muse, mutect2, varscan2
- AXL | c.1882C>A p.L628I (on ENST00000301178 / NM_021913.5; = p.L619I on NM_001699.6) | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV56569915; called by muse, mutect2, varscan2
- B3GNT7 | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.532); catalogued as COSV55006742; called by muse, mutect2, varscan2
- B4GALNT4 | c.212A>C p.Q71P | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as COSV57323927; called by muse, mutect2
- B9D2 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54684227; called by muse, mutect2
- BAG6 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 36/189 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.683); catalogued as rs375958321, COSV99276751; called by muse, mutect2, varscan2
- BAIAP2L1 | c.1307del p.P436Hfs*60 | Frame Shift Del (DEL) | VAF 20/65 reads (31%) | catalogued as rs1405664842, COSV50055281; called by mutect2, pindel, varscan2
- BAZ1A | c.1261C>T p.P421S | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as COSV62410658; called by muse, mutect2, varscan2
- BAZ1B | c.2251G>T p.A751S | Missense Mutation (SNP) | VAF 23/257 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1448250510, COSV59992004; called by muse, mutect2
- BAZ2B | c.4005G>T p.E1335D | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV54275949; called by muse, mutect2, varscan2
- BCAR1 | c.1802C>A p.A601D | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50786996; called by muse, mutect2, varscan2
- BCL11B | c.2212G>A p.A738T (on ENST00000357195 / NM_001282237.2; = p.A667T on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV100595383; called by muse, mutect2, varscan2
- BIN3 | c.338del p.K113Sfs*13 | Frame Shift Del (DEL) | VAF 34/130 reads (26%) | catalogued as rs776003776; called by mutect2, pindel, varscan2
- BMPR2 | c.1019T>A p.L340Q | Missense Mutation (SNP) | VAF 43/186 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM085279, COSV65810510; called by muse, mutect2, varscan2
- BMPR2 | c.1168G>T p.G390* | Nonsense Mutation (SNP) | VAF 27/83 reads (33%) | catalogued as COSV65808887, COSV65810518; called by muse, mutect2, varscan2
- BOC | c.2315A>C p.K772T | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV56352970; called by muse, mutect2, varscan2
- BPIFB3 | c.1417A>G p.T473A | Missense Mutation (SNP) | VAF 75/230 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100972333; called by muse, varscan2
- BPIFB4 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.935); catalogued as COSV100971373, COSV64951459; called by muse, mutect2, varscan2
- BPNT1 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs923244369, COSV59040324; called by muse, mutect2, varscan2
- BRCA2 | c.5227A>C p.S1743R | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.086); catalogued as COSV66455791; called by muse, mutect2, varscan2
- BRD2 | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV66373722; called by muse, mutect2, varscan2
- BRF2 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.53); catalogued as rs202236126, COSV55103648, COSV99604843; called by mutect2, varscan2
- BRS3 | c.323A>G p.Y108C | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1372961383, COSV101036523; called by muse, mutect2, varscan2
- BRSK1 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.898); catalogued as rs757271976, COSV58666512; called by muse, mutect2, varscan2
- BRSK1 | c.2215G>A p.A739T | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100442279; called by muse, mutect2, varscan2
- BTN3A3 | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 40/177 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.056); catalogued as COSV55072417; called by muse, mutect2
- C15orf39 | c.2245G>A p.A749T | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.82); PolyPhen benign (0.088); catalogued as COSV62297089; called by muse, mutect2, varscan2
- C16orf70 | c.1230del p.R411Gfs*6 | Frame Shift Del (DEL) | VAF 20/76 reads (26%) | catalogued as rs539297455, COSV54625370; called by mutect2, varscan2
- C1QL2 | c.809G>A p.G270E | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1442269448, COSV55606852; called by muse, mutect2, varscan2
- C1orf109 | c.610T>C p.*204Qext*16 | Nonstop Mutation (SNP) | VAF 66/218 reads (30%) | catalogued as COSV100787460; called by muse, mutect2, varscan2
- C1orf116 | c.1719dup p.C574Lfs*14 | Frame Shift Ins (INS) | VAF 16/64 reads (25%) | catalogued as rs780657010; called by mutect2, varscan2
- C3orf38 | c.532C>T p.L178F | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV59627585; called by muse, mutect2, varscan2
- C3orf62 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 65/198 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.025); catalogued as COSV55537818; called by muse, mutect2, varscan2
- C5AR1 | c.360G>A p.M120I | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100753988; called by muse, mutect2, varscan2
- C6orf136 | c.824G>A p.R275H (on ENST00000376473 / NM_001109938.3; = p.R141H on NM_145029.4) | Missense Mutation (SNP) | VAF 86/248 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs773937348, COSV53314719; called by muse, mutect2, varscan2
- C7 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV57475725; called by muse, mutect2, varscan2
- C9orf43 | c.668G>A p.G223D | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55912965; called by muse, varscan2
- C9orf43 | c.807+2T>C p.X269_splice | Splice Site (SNP) | VAF 24/102 reads (24%) | catalogued as COSV55912973; called by muse, varscan2
- C9orf64 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV59032708; called by muse, mutect2, varscan2
- CAB39L | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 70/237 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV61715443; called by muse, mutect2
- CACNA1A | c.6698G>A p.R2233H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1064793075, COSV64201150; called by muse, mutect2, varscan2
- CACNA1C | c.2132T>C p.V711A | Missense Mutation (SNP) | VAF 54/237 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV59732926; called by muse, varscan2
- CACNA1F | c.3630G>T p.Q1210H | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59905072; called by muse, mutect2, varscan2
- CACNA1H | c.6570del p.C2191Afs*26 | Frame Shift Del (DEL) | VAF 9/31 reads (29%) | catalogued as rs760298114; called by mutect2, pindel, varscan2
- CACNB1 | c.151T>C p.S51P | Missense Mutation (SNP) | VAF 42/181 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59999117; called by muse, mutect2, varscan2
- CADM2 | c.160C>A p.L54I (on ENST00000407528 / NM_001167674.2; = p.L56I on NM_153184.4) | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.999); catalogued as COSV101059919, COSV67382456; called by muse, varscan2
- CADPS2 | c.3216C>A p.D1072E | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); catalogued as COSV57364577; called by muse, mutect2, varscan2
- CARD11 | c.1663del p.R555Gfs*45 | Frame Shift Del (DEL) | VAF 14/53 reads (26%) | catalogued as rs762770988, COSV62756627; called by mutect2, pindel, varscan2
- CARD6 | c.16A>G p.T6A | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV54566887; called by muse, mutect2, varscan2
- CARS2 | c.1579G>A p.D527N | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150780076; called by muse, mutect2, varscan2
- CASK | c.2306A>G p.Y769C (on ENST00000378163 / NM_001367721.1; = p.Y764C on NM_003688.3) | Missense Mutation (SNP) | VAF 69/197 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59368863; called by muse, mutect2, varscan2
- CASKIN1 | c.635G>A p.G212D | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1420097021, COSV58873578; called by muse, mutect2, varscan2
- CASP5 | c.560del p.K187Rfs*33 | Frame Shift Del (DEL) | VAF 73/314 reads (23%) | catalogued as rs753743648; called by mutect2, pindel, varscan2
- CASR | c.2572C>T p.P858S (on ENST00000490131; = p.P935S on NM_000388.4) | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.022); catalogued as COSV56138603; called by muse, mutect2, varscan2
- CASZ1 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.012); catalogued as rs1361254433, COSV59736328; called by muse, mutect2, varscan2
- CATSPERB | c.3290A>G p.Q1097R | Missense Mutation (SNP) | VAF 30/290 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1427140366, COSV56428377; called by muse, mutect2
- CAVIN1 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 101/440 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV63812126; called by muse, mutect2, varscan2
- CBLB | c.1522C>T p.P508S | Missense Mutation (SNP) | VAF 144/503 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51429392; called by muse, mutect2, varscan2
- CBLN1 | c.320del p.P107Rfs*13 | Frame Shift Del (DEL) | VAF 72/284 reads (25%) | catalogued as COSV54654795, COSV54654896; called by mutect2, pindel
- CBWD1 | c.194A>G p.E65G | Missense Mutation (SNP) | VAF 127/662 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100070755; called by muse, mutect2, varscan2
- CBX4 | c.690dup p.N231Qfs*81 | Frame Shift Ins (INS) | VAF 39/146 reads (27%) | catalogued as rs772839792; called by mutect2, varscan2
- CCDC25 | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 84/314 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.938); catalogued as COSV62958969; called by muse, mutect2, varscan2
- CCDC39 | c.1481A>G p.K494R | Missense Mutation (SNP) | VAF 57/200 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as COSV56486632; called by muse, varscan2
- CCDC51 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 60/169 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV56491045; called by muse, mutect2, varscan2
- CCDC62 | c.770C>T p.T257I | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.75); catalogued as rs1426015988, COSV53434682; called by muse, mutect2, varscan2
- CCDC66 | c.792dup p.A265Sfs*9 (on ENST00000394672 / NM_001353147.1; = p.A231Sfs*9 on NM_001012506.5 and 6 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 18/122 reads (15%) | catalogued as rs770432647; called by mutect2, varscan2
- CCDC73 | c.3219A>T p.E1073D | Missense Mutation (SNP) | VAF 62/228 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as rs1230820117, COSV58800203; called by muse, mutect2, varscan2
- CCDC74A | c.617T>C p.L206P | Missense Mutation (SNP) | VAF 64/250 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs374861718; called by muse, mutect2
- CCDC81 | c.1208C>T p.P403L (on ENST00000445632 / NM_001156474.2; = p.P313L on NM_021827.4) | Missense Mutation (SNP) | VAF 60/184 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as rs771597311, COSV53577291; called by muse, varscan2
- CCDC85A | c.840G>T p.E280D | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.82); catalogued as COSV68148498; called by muse, mutect2, varscan2
- CCDC88B | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57266748; called by muse, mutect2, varscan2
- CCDC88C | c.5527C>T p.H1843Y | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV100484772; called by muse, mutect2
- CCDC9 | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs539655267, COSV55721311; called by muse, mutect2, varscan2
- CCDC9 | c.598C>T p.R200* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as rs773212656, COSV99699611; called by muse, mutect2
- CCDC9B | c.609dup p.T204Hfs*56 | Frame Shift Ins (INS) | VAF 15/68 reads (22%) | catalogued as rs772754432; called by mutect2, varscan2
- CCL14 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs771441014; called by muse, mutect2, varscan2
- CCN5 | c.349T>C p.C117R | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51937702; called by muse, mutect2, varscan2
- CCNB1IP1 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 84/266 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs772896629, COSV62302759; called by muse, mutect2, varscan2
- CCNB1IP1 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.069); catalogued as COSV62302995; called by muse, mutect2, varscan2
- CCND1 | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 38/123 reads (31%) | catalogued as COSV57121723; called by muse, mutect2, varscan2
- CCNK | c.568A>G p.N190D | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66275077; called by muse, mutect2, varscan2
- CCPG1 | c.235A>C p.T79P | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as COSV100197060; called by muse, mutect2, varscan2
- CCZ1 | c.1339C>T p.R447W | Missense Mutation (SNP) | VAF 64/416 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1243957427; called by mutect2, varscan2
- CD101 | c.1145T>G p.V382G | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.398); catalogued as COSV56718774; called by muse, mutect2, varscan2
- CD163 | c.2513G>A p.R838H | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.984); catalogued as rs1401975667, COSV63133765; called by muse, mutect2, varscan2
- CD2AP | c.1244A>G p.K415R | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.998); catalogued as COSV63761308; called by muse, mutect2, varscan2
- CD96 | c.76del p.T26Qfs*18 | Frame Shift Del (DEL) | VAF 25/90 reads (28%) | catalogued as COSV99342880; called by mutect2, pindel, varscan2
- CDAN1 | c.1390C>T p.R464* | Nonsense Mutation (SNP) | VAF 28/86 reads (33%) | catalogued as COSV62332108; called by muse, mutect2, varscan2
- CDC14A | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as rs1343278493, COSV60559469; called by muse, mutect2, varscan2
- CDC25B | c.1558T>C p.Y520H (on ENST00000245960 / NM_021873.3; = p.Y506H on NM_004358.4) | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55657454; called by muse, mutect2, varscan2
- CDC42BPA | c.5126del p.P1709Qfs*56 (on ENST00000334218 / NM_001366019.2; = p.P1696Qfs*56 on NM_003607.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 30/111 reads (27%) | catalogued as rs869029351; called by pindel, varscan2
- CDC42BPA | c.4933G>A p.A1645T (on ENST00000334218 / NM_001366019.2; = p.A1632T on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.99); catalogued as rs756838979, COSV62013394; called by muse, mutect2, varscan2
- CDC42BPG | c.3908G>A p.G1303D | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.239); catalogued as COSV100712036; called by muse, mutect2, varscan2
- CDCA8 | c.85G>T p.D29Y | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100523560; called by muse, mutect2
- CDH12 | c.1505A>C p.K502T | Missense Mutation (SNP) | VAF 40/278 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.515); catalogued as COSV66415372; called by muse, mutect2
- CDH17 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 84/260 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.02); catalogued as COSV50330946; called by muse, varscan2
- CDK14 | c.1174G>A p.A392T (on ENST00000380050 / NM_001287135.2; = p.A374T on NM_012395.3) | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as rs112642464, COSV56037071, COSV56039502; called by muse, mutect2, varscan2
- CEL | c.619del p.D207Tfs*41 (on ENST00000673714; = p.D204Tfs*41 on NM_001807.6) | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | catalogued as rs754393686, COSV60827096; called by mutect2, varscan2
- CELF4 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs148456424; called by muse, mutect2, varscan2
- CENPX | c.160G>A p.V54M (on ENST00000392359 / NM_001271006.2; = p.V36M on NM_144998.4) | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.632); catalogued as rs780161606, COSV60711790; called by muse, mutect2, varscan2
- CEP162 | c.2665C>T p.L889F | Missense Mutation (SNP) | VAF 51/172 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761104675, COSV100002602; called by muse, varscan2
- CEP170B | c.1819G>A p.A607T (on ENST00000453495; = p.A536T on NM_015005.3) | Missense Mutation (SNP) | VAF 65/140 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.209); catalogued as rs1451858931, COSV101371468; called by muse, mutect2, varscan2
- CEP72 | c.1249G>A p.A417T | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs1461378127, COSV53793806; called by muse, mutect2, varscan2
- CEP72 | c.1697G>A p.G566D | Missense Mutation (SNP) | VAF 93/318 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV53793823; called by muse, varscan2
- CEP95 | c.2152C>T p.R718* | Nonsense Mutation (SNP) | VAF 54/180 reads (30%) | catalogued as rs567605055, COSV73609379; called by muse, mutect2, varscan2
- CES3 | c.742T>C p.F248L | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100309875, COSV100310066; called by muse, varscan2
- CES3 | c.1267G>A p.V423I | Missense Mutation (SNP) | VAF 63/157 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.094); catalogued as rs201768671, COSV57594159; called by muse, mutect2, varscan2
- CFAP46 | c.5926A>G p.T1976A | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99584411; called by muse, mutect2, varscan2
- CFAP46 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs369847869; called by muse, mutect2, varscan2
- CFAP47 | c.2064G>T p.E688D | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.025); catalogued as COSV52886675; called by muse, mutect2, varscan2
- CHD3 | c.703G>T p.A235S | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.054); catalogued as COSV100391013; called by muse, mutect2, varscan2
- CHD4 | c.1483T>C p.W495R (on ENST00000357008 / NM_001363606.2; = p.W508R on NM_001273.5) | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58903683; called by muse, mutect2, varscan2
- CHD7 | c.6773A>G p.E2258G | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as COSV71112089; called by muse, mutect2, varscan2
- CHD8 | c.5783G>A p.R1928Q (on ENST00000646647 / NM_001170629.2; = p.R1649Q on NM_020920.4) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.32); catalogued as rs1450857291, COSV63036549, COSV63037457; called by muse, varscan2
- CHL1 | c.144_145insA p.F49Ifs*3 | Frame Shift Ins (INS) | VAF 25/111 reads (23%) | catalogued as COSV56596346; called by mutect2, pindel, varscan2
- CHMP7 | c.966del p.F322Lfs*8 | Frame Shift Del (DEL) | VAF 24/102 reads (24%) | catalogued as rs1207051707; called by mutect2, pindel, varscan2
- CHORDC1 | c.115-1G>T p.X39_splice | Splice Site (SNP) | VAF 106/364 reads (29%) | catalogued as rs772851564, COSV57706314, COSV57706721; called by muse, mutect2, varscan2
- CHRNE | c.1466C>A p.P489Q | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.669); catalogued as COSV53418538; called by muse, mutect2, varscan2
- CHTF18 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs768976698, COSV50101025; called by muse, mutect2, varscan2
- CIAO3 | c.953del p.G318Afs*27 | Frame Shift Del (DEL) | VAF 8/27 reads (30%) | catalogued as rs1442970889; called by mutect2, pindel, varscan2
- CIART | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 70/220 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs587665092, COSV51744680; called by muse, mutect2, varscan2
- CIC | c.1766G>A p.R589Q | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as rs202152564; called by muse, mutect2, varscan2
- CILP | c.2051C>T p.S684L | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as rs775992863, COSV56025237; called by muse, mutect2, varscan2
- CLEC16A | c.2503A>G p.T835A | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.079); catalogued as rs1190412022, COSV99901330; called by muse, mutect2
- CLINT1 | c.611T>C p.L204P | Missense Mutation (SNP) | VAF 90/318 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.418); catalogued as COSV51625882; called by muse, mutect2, varscan2
- CLN3 | c.589G>A p.A197T (on ENST00000360019 / NM_001286104.2; = p.A221T on NM_000086.2) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.243); catalogued as rs748636727, COSV61106249; called by muse, mutect2, varscan2
- CLP1 | c.337C>T p.R113* | Nonsense Mutation (SNP) | VAF 28/106 reads (26%) | catalogued as rs1443018290, COSV57054867; called by muse, mutect2, varscan2
- CLPTM1 | c.1625G>A p.R542H | Missense Mutation (SNP) | VAF 48/177 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61612254; called by muse, mutect2, varscan2
- CLSTN3 | c.1829G>A p.R610H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.04); catalogued as rs765424120, COSV56938119; called by muse, mutect2, varscan2
- CLTCL1 | c.543G>A p.M181I | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.808); catalogued as COSV99594831; called by muse, mutect2, varscan2
- CMTM5 | c.377del p.P126Rfs*55 | Frame Shift Del (DEL) | VAF 25/79 reads (32%) | catalogued as rs751921758; called by mutect2, varscan2
- CMYA5 | c.4618A>G p.K1540E | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1273836420, COSV71406715; called by muse, mutect2, varscan2
- CNGB1 | c.1159G>A p.V387M | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.271); catalogued as rs772522514, COSV51902301; called by muse, mutect2, varscan2
- CNNM1 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV63202150; called by muse, mutect2, varscan2
- CNOT1 | c.1130T>C p.V377A | Missense Mutation (SNP) | VAF 63/220 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as COSV57772974; called by muse, mutect2, varscan2
- CNOT3 | c.1897C>T p.R633C | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55364618; called by muse, mutect2, varscan2
- CNPY4 | c.41dup p.L14Ffs*17 | Frame Shift Ins (INS) | VAF 119/360 reads (33%) | catalogued as rs1347948509; called by mutect2, varscan2
- CNTNAP1 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 64/221 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.401); catalogued as rs1342471394, COSV52851475; called by muse, mutect2, varscan2
- CNTNAP2 | c.531A>C p.E177D | Missense Mutation (SNP) | VAF 76/281 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV62197769; called by muse, mutect2, varscan2
- CNTNAP3 | c.2942G>T p.G981V | Missense Mutation (SNP) | VAF 59/257 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs959615268, COSV99904522; called by muse, mutect2, varscan2
- CNTROB | c.2699del p.G900Efs*34 | Frame Shift Del (DEL) | VAF 15/58 reads (26%) | catalogued as rs35508310, COSV66608279; called by mutect2, pindel, varscan2
- COASY | c.961C>A p.L321I | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV99888322; called by muse, mutect2, varscan2
- COG1 | c.2816C>T p.P939L | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); catalogued as rs763565694, COSV55430356; called by muse, mutect2, varscan2
- COL11A1 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.978); catalogued as COSV62186745; called by muse, mutect2, varscan2
- COL17A1 | c.364C>A p.P122T | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.715); catalogued as COSV62227458; called by mutect2, varscan2
- COL18A1 | c.1822del p.R608Gfs*27 (on ENST00000359759 / NM_130444.3; = p.R373Gfs*27 on NM_030582.4) | Frame Shift Del (DEL) | VAF 9/51 reads (18%) | catalogued as COSV62702989; called by mutect2, pindel, varscan2
- COL3A1 | c.3100C>T p.R1034C | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1178112512, COSV58582183; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A2 | c.3925+2T>C p.X1309_splice | Splice Site (SNP) | VAF 30/74 reads (41%) | catalogued as COSV100880145; called by muse, mutect2
- COL6A5 | c.6265G>T p.E2089* (on ENST00000312481; = p.E2085* on NM_153264.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 29/106 reads (27%) | catalogued as COSV55206109; called by muse, mutect2, varscan2
- COL7A1 | c.4858C>T p.R1620W | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs781705982, COSV100095658; called by muse, mutect2, varscan2
- COL7A1 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs752101927, COSV60396802; called by muse, mutect2, varscan2
- COL9A1 | c.915T>A p.G305= | Splice Region (SNP) | VAF 29/94 reads (31%) | catalogued as COSV57886212; called by muse, mutect2, varscan2
- COLGALT2 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs768723326, COSV62727701; called by muse, mutect2, varscan2
- COPG1 | c.1936T>C p.Y646H | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59114663; called by muse, mutect2, varscan2
- COPS3 | c.1048A>G p.S350G | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as rs201493311, COSV52006026; called by muse, mutect2, varscan2
- CORO2A | c.238G>A p.G80R | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs2231658; called by muse, mutect2, varscan2
- CORO7 | c.2450G>A p.R817Q | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768577818, COSV52031178; called by muse, mutect2, varscan2
- COX6A2 | c.275del p.T92Rfs*? | Frame Shift Del (DEL) | VAF 24/109 reads (22%) | catalogued as COSV54932196, COSV54932951; called by mutect2, pindel, varscan2
- CPLX4 | c.28A>G p.S10G | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV55313918; called by muse, mutect2
- CR2 | c.624del p.T209Hfs*10 | Frame Shift Del (DEL) | VAF 92/306 reads (30%) | catalogued as rs747832403; called by mutect2, varscan2
- CRACDL | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1293975643, COSV67408702; called by muse, mutect2, varscan2
- CREB3L2 | c.1418T>C p.L473P | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.491); catalogued as COSV57796539; called by muse, mutect2, varscan2
- CRTC1 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV58719968; called by muse, mutect2, varscan2
- CRYGA | c.476del p.G159Vfs*9 | Frame Shift Del (DEL) | VAF 55/156 reads (35%) | catalogued as rs762650691; called by mutect2, pindel, varscan2
- CSAD | c.1282C>T p.P428S (on ENST00000444623 / NM_001244705.2; = p.P455S on NM_015989.5) | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.051); catalogued as COSV99914515; called by muse, mutect2
- CSF1R | c.2512G>A p.V838I | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs690016557, CM1311990, COSV53836780; called by muse, mutect2, varscan2
- CSF2RA | c.109A>G p.N37D | Missense Mutation (SNP) | VAF 79/314 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs775556939, COSV62625177; called by muse, mutect2, varscan2
- CSGALNACT1 | c.832C>T p.Q278* | Nonsense Mutation (SNP) | VAF 73/266 reads (27%) | catalogued as COSV100174681; called by muse, mutect2, varscan2
- CSK | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.527); catalogued as rs754136671, COSV54974351; called by muse, mutect2, varscan2
- CSMD2 | c.499C>A p.L167I | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as COSV99588359; called by muse, mutect2, varscan2
- CSNK2A2 | c.246G>T p.E82D | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52642510; called by muse, mutect2, varscan2
- CSPG4 | c.4421C>A p.P1474H | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57896867; called by muse, mutect2, varscan2
- CSPG4 | c.4067C>T p.A1356V | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs1432408515, COSV100413675; called by muse, mutect2, varscan2
- CTAG2 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.293); catalogued as rs373719423, COSV55994852; called by muse, mutect2, varscan2
- CTDSP1 | c.699G>T p.E233D | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56090165; called by muse, mutect2, varscan2
- CTNNA3 | c.793C>A p.P265T | Missense Mutation (SNP) | VAF 69/211 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV65594394; called by muse, mutect2, varscan2
- CTPS2 | c.904G>A p.A302T | Missense Mutation (SNP) | VAF 14/187 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); catalogued as COSV100826762; called by muse, mutect2
- CTSC | c.1318C>T p.R440W | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.736); catalogued as rs754353507, COSV57058019; called by muse, mutect2, varscan2
- CTSL | c.450G>T p.Q150H | Missense Mutation (SNP) | VAF 46/188 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs772325261, COSV100446621, COSV58246462; called by muse, varscan2
- CTSW | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.806); catalogued as rs760246700, COSV57171945; called by muse, mutect2, varscan2
- CUBN | c.6733G>A p.A2245T | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.06); catalogued as rs1237546086; called by muse, mutect2
- CUL4B | c.1112T>A p.L371H | Missense Mutation (SNP) | VAF 80/271 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60688419; called by muse, mutect2, varscan2
- CUL4B | c.458A>G p.Q153R | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV100340342; called by muse, varscan2
- CYLC1 | c.647C>G p.T216R | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0.364); catalogued as COSV61413044; called by muse, mutect2, varscan2
- CYP26B1 | c.343A>G p.T115A | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV99134430; called by muse, mutect2, varscan2
- CYP4F3 | c.1471G>A p.V491I | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as rs375318772, COSV55409460, COSV55410867; called by muse, mutect2, varscan2
- CYP4V2 | c.981G>C p.M327I | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs770074074, COSV66506231; called by muse, mutect2, varscan2
- CYP4Z1 | c.1509dup p.V504Sfs*10 | Frame Shift Ins (INS) | VAF 48/142 reads (34%) | catalogued as rs759035167; called by mutect2, varscan2
- CYREN | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV99313144; called by muse, mutect2, varscan2
- DAAM2 | c.2729T>C p.V910A (on ENST00000274867 / NM_001201427.2; = p.V909A on NM_015345.3) | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.523); catalogued as COSV51333493; called by muse, mutect2, varscan2
- DAB2IP | c.3073del p.H1025Tfs*5 (on ENST00000408936; = p.H997Tfs*5 on NM_032552.3) | Frame Shift Del (DEL) | VAF 13/53 reads (25%) | catalogued as rs751187768; called by mutect2, varscan2
- DACH2 | c.1567A>C p.K523Q | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100912973, COSV64169192; called by muse, mutect2, varscan2
- DACT1 | c.1594G>A p.V532M | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.083); catalogued as rs200502429, COSV60021461; called by muse, varscan2
- DAD1 | c.59C>A p.T20N | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51663377; called by muse, mutect2, varscan2
- DAPK1 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as rs749825789, COSV63788508, COSV63791956; called by muse, mutect2, varscan2
- DARS2 | c.773A>G p.Y258C | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53407448; called by muse, mutect2
- DAZAP1 | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 60/155 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1461918261, COSV51833611; called by muse, mutect2, varscan2
- DBT | c.1436T>C p.L479P | Missense Mutation (SNP) | VAF 83/248 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV64497723; called by muse, mutect2, varscan2
- DCAF6 | c.1661T>C p.V554A (on ENST00000312263 / NM_001349778.1; = p.V574A on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); catalogued as COSV100394114; called by muse, mutect2, varscan2
- DCBLD2 | c.778A>G p.K260E | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58790559; called by muse, mutect2, varscan2
- DCHS1 | c.5428A>G p.M1810V | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1347182620, COSV55037612; called by muse, mutect2, varscan2
- DCST1 | c.1103C>T p.A368V | Missense Mutation (SNP) | VAF 56/155 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV55060281; called by muse, varscan2
- DDR1 | c.994C>T p.R332W | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759421254, COSV61321965; called by muse, mutect2, varscan2
- DDR1 | c.1565G>A p.R522H | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.32); catalogued as rs145280414; called by muse, mutect2, varscan2
- DDX31 | c.1768C>T p.R590W | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754917433, COSV64649948; called by muse, mutect2, varscan2
- DDX50 | c.190del p.S64Lfs*3 | Frame Shift Del (DEL) | VAF 82/339 reads (24%) | catalogued as COSV65292520; called by mutect2, pindel, varscan2
- DDX60L | c.1314G>A p.M438I | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs756156510, COSV52715546; called by muse, mutect2, varscan2
- DENND1C | c.1222_1224del p.E408del | In Frame Del (DEL) | VAF 21/71 reads (30%) | catalogued as rs774558415; called by mutect2, pindel, varscan2
- DENND2B | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 55/154 reads (36%) | catalogued as rs138818386; called by muse, mutect2, varscan2
- DENND2D | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1004634527, COSV100718608, COSV62958412; called by muse, mutect2, varscan2
- DENND4C | c.5083C>T p.Q1695* (on ENST00000434457 / NM_001330640.2; = p.Q1646* on NM_017925.7) | Nonsense Mutation (SNP) | VAF 38/120 reads (32%) | catalogued as COSV63009114; called by muse, mutect2, varscan2
- DGKD | c.3268C>A p.P1090T (on ENST00000264057 / NM_152879.3; = p.P1046T on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/157 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0.066); catalogued as COSV51057018; called by muse, mutect2, varscan2
- DGKK | c.2462G>A p.R821H | Missense Mutation (SNP) | VAF 85/266 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs782287521, COSV101052946; called by muse, mutect2, varscan2
- DHRS13 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 72/218 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV60454482; called by muse, mutect2, varscan2
- DHX16 | c.1045C>T p.Q349* | Nonsense Mutation (SNP) | VAF 22/58 reads (38%) | catalogued as COSV64563588, COSV64564477; called by muse, mutect2, varscan2
- DHX33 | c.1729-1G>C p.X577_splice | Splice Site (SNP) | VAF 28/92 reads (30%) | catalogued as rs1241807843, COSV56579586; called by muse, mutect2, varscan2
- DHX34 | c.908C>A p.P303H | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV60895938; called by muse, varscan2
- DIP2B | c.1318-1G>T p.X440_splice | Splice Site (SNP) | VAF 19/88 reads (22%) | catalogued as COSV56586017; called by muse, mutect2, varscan2
- DIS3L | c.1336A>G p.M446V (on ENST00000319212 / NM_001143688.3; = p.M363V on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV59912913; called by muse, mutect2, varscan2
- DISP2 | c.2551G>A p.A851T | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.09); catalogued as COSV51125691; called by muse, mutect2, varscan2
- DKK2 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs539488952, COSV53393778; called by muse, mutect2, varscan2
- DKKL1 | c.437A>T p.K146M | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.906); catalogued as COSV55562733; called by muse, mutect2, varscan2
- DLEC1 | c.367A>G p.S123G | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs775199798, COSV57301414; called by muse, mutect2, varscan2
- DLGAP2 | c.2678C>T p.A893V | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs766613957, COSV70099879; called by muse, mutect2, varscan2
- DLL4 | c.1321G>A p.V441I | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374162819; called by muse, mutect2, varscan2
- DLX4 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV53591923; called by muse, mutect2, varscan2
- DLX5 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV56032274; called by muse, varscan2
- DMBT1 | c.6178C>T p.R2060C (on ENST00000338354 / NM_001377530.1; = p.R1303C on NM_004406.3) | Missense Mutation (SNP) | VAF 68/205 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.974); catalogued as rs369485069; called by muse, mutect2, varscan2
- DMD | c.3805C>T p.H1269Y | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs151150099, COSV100817349, COSV63765106; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DMD | c.2500G>A p.A834T | Missense Mutation (SNP) | VAF 59/189 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs767063127, COSV63754561; called by muse, mutect2, varscan2
- DMKN | c.1364del p.G455Efs*19 | Frame Shift Del (DEL) | VAF 19/77 reads (25%) | catalogued as rs758253239; called by mutect2, pindel, varscan2
- DMKN | c.586G>T p.G196* | Nonsense Mutation (SNP) | VAF 56/158 reads (35%) | catalogued as COSV60087094; called by muse, mutect2, varscan2
- DMRT2 | c.985G>T p.A329S | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.612); catalogued as COSV52402232; called by muse, mutect2, varscan2
- DMXL2 | c.3794A>G p.D1265G | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51848784; called by muse, mutect2, varscan2
- DNAAF5 | c.2366A>G p.Y789C | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.49); catalogued as COSV52414198, COSV52418027; called by muse, mutect2, varscan2
- DNAH1 | c.7717C>T p.R2573C | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755999256, COSV70230483; called by muse, mutect2, varscan2
- DNAH10 | c.2950C>T p.R984W (on ENST00000409039; = p.R923W on NM_207437.3) | Missense Mutation (SNP) | VAF 65/166 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs138047908; called by muse, mutect2, varscan2
- DNAH11 | c.3587C>T p.T1196M | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.606); catalogued as rs779537030, COSV60992989; called by muse, mutect2, varscan2
- DNAH2 | c.1076G>A p.S359N | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV50015595; called by muse, mutect2, varscan2
- DNAH3 | c.7808T>C p.V2603A | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54529253; called by muse, mutect2
- DNAH8 | c.5484C>A p.C1828* | Nonsense Mutation (SNP) | VAF 38/130 reads (29%) | catalogued as COSV59441413; called by muse, mutect2, varscan2
- DNAH9 | c.11342C>A p.P3781Q | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV52356020; called by muse, mutect2, varscan2
- DNAI4 | c.89del p.K30Rfs*28 | Frame Shift Del (DEL) | VAF 30/129 reads (23%) | catalogued as rs774662919; called by mutect2, pindel, varscan2
- DNAJA1 | c.650A>G p.K217R | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.026); catalogued as COSV58310659; called by muse, mutect2, varscan2
- DNAJB13 | c.492G>A p.R164= | Splice Region (SNP) | VAF 8/19 reads (42%) | catalogued as COSV60269843; called by muse, mutect2, varscan2
- DOCK1 | c.4559A>G p.N1520S | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.84); catalogued as rs769437313, COSV54745058; called by muse, varscan2
- DOCK11 | c.2737A>G p.R913G | Missense Mutation (SNP) | VAF 134/518 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV99353458; called by muse, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 46/210 reads (22%) | catalogued as rs782552436; called by pindel, varscan2
- DOK6 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.077); catalogued as rs1417394627, COSV66927138; called by muse, varscan2
- DOK6 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.749); catalogued as rs771061011, COSV66929502; called by muse, varscan2
- DONSON | c.1284G>T p.Q428H | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51661759; called by muse, mutect2, varscan2
- DPAGT1 | c.935G>A p.G312D | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.076); catalogued as COSV99597892; called by muse, mutect2, varscan2
- DPP6 | c.1940C>T p.T647M (on ENST00000377770 / NM_001364500.2; = p.T585M on NM_001936.5) | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs546439141, COSV59622557; called by muse, mutect2
- DPPA4 | c.610G>T p.A204S | Missense Mutation (SNP) | VAF 44/212 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV59511082; called by muse, mutect2, varscan2
- DPPA4 | c.491A>G p.H164R | Missense Mutation (SNP) | VAF 80/243 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0.01); catalogued as COSV59511092, COSV59512460; called by muse, mutect2
- DPYS | c.1364T>A p.V455D | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV60909953; called by muse, mutect2, varscan2
- DPYSL2 | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs765937076, COSV60784077; called by muse, mutect2, varscan2
- DRC3 | c.623G>T p.S208I | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as COSV58264204; called by muse, mutect2, varscan2
- DRD5 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.675); catalogued as rs773943990, COSV58578778; called by muse, mutect2, varscan2
- DSCAML1 | c.373G>A p.D125N (on ENST00000321322; = p.D65N on NM_020693.4) | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs770650408, COSV58394306; called by muse, mutect2, varscan2
- DSN1 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.973); catalogued as rs761761654, COSV65519442; called by muse, mutect2, varscan2
- DST | c.20441A>G p.Q6814R (on ENST00000361203 / NM_001374722.1; = p.Q4511R on NM_015548.5) | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.96); catalogued as COSV55021707; called by muse, mutect2, varscan2
- DST | c.4759C>A p.L1587I | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99753906; called by muse, mutect2, varscan2
- DUOX1 | c.3191A>G p.Y1064C | Missense Mutation (SNP) | VAF 13/176 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV100367839; called by muse, mutect2
- DUOX2 | c.4612C>T p.R1538* | Nonsense Mutation (SNP) | VAF 39/126 reads (31%) | catalogued as rs780309467, COSV66532437; called by muse, mutect2, varscan2
- DUOX2 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs756746436, COSV99972981, COSV99973026; called by muse, varscan2
- DUSP10 | c.799C>A p.L267M | Missense Mutation (SNP) | VAF 61/165 reads (37%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.588); catalogued as COSV60458308; called by muse, mutect2, varscan2
- DUSP9 | c.475G>A p.V159M | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.372); catalogued as rs782644901, COSV61437794; called by muse, mutect2, varscan2
- DYNC1LI1 | c.713T>A p.I238N | Missense Mutation (SNP) | VAF 55/174 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV56128057; called by muse, mutect2, varscan2
- DYSF | c.175del p.L59Wfs*92 | Frame Shift Del (DEL) | VAF 39/118 reads (33%) | catalogued as rs1558967217, COSV50342480; called by mutect2, pindel, varscan2
- DYTN | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs183705947; called by muse, varscan2
- DZANK1 | c.1229G>A p.R410H (on ENST00000262547 / NM_001099407.1; = p.R211H on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs750727435, COSV52748522, COSV52749420; called by muse, mutect2, varscan2
- ECI2 | c.123G>T p.K41N (on ENST00000380118 / NM_206836.3; = p.K11N on NM_006117.2) | Missense Mutation (SNP) | VAF 101/296 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.216); catalogued as COSV100326407; called by muse, mutect2, varscan2
- EDN3 | c.554C>T p.T185M | Missense Mutation (SNP) | VAF 55/161 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.749); catalogued as rs368327225, CM1310571; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EDNRB | c.536C>T p.P179L (on ENST00000377211 / NM_001201397.1; = p.P89L on NM_000115.5) | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV57524395; called by muse, mutect2, varscan2
- EEF1A2 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 60/141 reads (43%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.079); catalogued as rs778585590, COSV53206736; called by muse, mutect2, varscan2
- EEPD1 | c.256G>A p.V86I | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.04); catalogued as rs370097837; called by muse, mutect2, varscan2
- EFCAB5 | c.1256A>G p.H419R | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs776685160, COSV57931840; called by muse, mutect2
- EFCAB6 | c.992A>G p.Y331C | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV53065550; called by muse, mutect2, varscan2
- EGLN1 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 71/171 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs1461203092, CM150261, COSV64147716; called by muse, mutect2, varscan2
- EHMT2 | c.1635G>T p.E545D | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.776); catalogued as COSV64996482; called by muse, mutect2, varscan2
- EIF3C | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 231/1501 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.029); catalogued as COSV100528123; called by muse, mutect2, varscan2
- EIF3L | c.386T>C p.L129P | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV101094486; called by muse, mutect2
- EIF4H | c.164A>G p.Q55R | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.656); catalogued as COSV56082489; called by muse, mutect2, varscan2
- ELAVL1 | c.874A>G p.M292V | Missense Mutation (SNP) | VAF 61/252 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV60967100; called by muse, mutect2, varscan2
- ELK3 | c.1028C>T p.P343L | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs758120639, COSV57385410; called by muse, mutect2, varscan2
- ELL | c.1610G>A p.R537H | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV53213475; called by muse, mutect2, varscan2
- ELP1 | c.2797C>T p.R933W | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs763312635, COSV65898292; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ELP2 | c.1586G>T p.G529V | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.046); catalogued as COSV100626777; called by muse, mutect2, varscan2
- EMC3 | c.323C>T p.T108I | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.424); catalogued as COSV55278570; called by muse, mutect2, varscan2
- EML3 | c.913A>G p.T305A | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV53883044; called by muse, mutect2
- ENAM | c.2695G>A p.A899T | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.615); catalogued as rs747987620, COSV68536239; called by muse, mutect2, varscan2
- ENO3 | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV52775950, COSV52777965; called by muse, mutect2, varscan2
- ENTPD6 | c.1000T>C p.W334R | Missense Mutation (SNP) | VAF 83/271 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV61751413; called by muse, mutect2, varscan2
- EOMES | c.1924C>T p.R642* | Nonsense Mutation (SNP) | VAF 60/181 reads (33%) | catalogued as rs768922132, COSV55413110; called by muse, mutect2, varscan2
- EP400 | c.2503G>A p.A835T | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as rs747796056, COSV100202276, COSV57775815; called by mutect2, varscan2
- EP400 | c.2659G>A p.A887T | Missense Mutation (SNP) | VAF 92/250 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs377249323, COSV57764575; called by muse, varscan2
- EPB42 | c.733C>T p.R245C (on ENST00000441366 / NM_001114134.2; = p.R275C on NM_000119.3) | Missense Mutation (SNP) | VAF 69/173 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.939); catalogued as rs1327802787, COSV55750203; called by muse, mutect2, varscan2
- EPHA6 | c.1969G>A p.V657I (on ENST00000389672 / NM_001080448.3; = p.V49I on NM_173655.4) | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as rs753848380, COSV67592998; called by muse, mutect2, varscan2
- EPHB3 | c.776A>G p.D259G | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57806912; called by muse, mutect2, varscan2
- EPHX4 | c.313T>A p.F105I | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.823); catalogued as COSV64889635; called by muse, mutect2, varscan2
- EPPK1 | c.1906C>T p.R636W | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs569166266, COSV73261400; called by muse, mutect2, varscan2
- EPS15L1 | c.1288C>T p.R430W | Missense Mutation (SNP) | VAF 81/270 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1297220753, COSV50167451; called by muse, mutect2, varscan2
- EPS8L1 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as COSV52383136; called by muse, mutect2, varscan2
- ERAP1 | c.1693G>A p.V565I | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1487807455, COSV57089067; called by muse, mutect2, varscan2
- ERAS | c.56C>A p.P19H | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.253); catalogued as COSV54432978; called by muse, mutect2
- ERBB4 | c.119_120dup p.D41Lfs*26 | Frame Shift Ins (INS) | VAF 37/139 reads (27%) | catalogued as COSV53588699; called by mutect2, varscan2
- ERCC2 | c.1163T>C p.I388T | Missense Mutation (SNP) | VAF 52/156 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); catalogued as COSV55542098; called by muse, mutect2, varscan2
- ERCC4 | c.680C>T p.T227I | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.137); catalogued as COSV61312501; called by muse, mutect2, varscan2
- ERG | c.1232del p.P411Rfs*25 (on ENST00000398919 / NM_001243428.1; = p.P387Rfs*25 on NM_004449.4) | Frame Shift Del (DEL) | VAF 41/130 reads (32%) | catalogued as COSV55735041; called by mutect2, pindel, varscan2
- ERN2 | c.466del p.R156Afs*43 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | catalogued as rs760310462, COSV56838101; called by mutect2, pindel, varscan2
- ESD | c.50A>G p.K17R | Missense Mutation (SNP) | VAF 50/223 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.041); catalogued as COSV66340457; called by muse, mutect2, varscan2
- ESR1 | c.871C>A p.L291I | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as rs746807379, COSV52793641; called by muse, mutect2, varscan2
- ETAA1 | c.2035A>G p.M679V | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs749356019, COSV55473658; called by muse, varscan2
- ETV1 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.934); catalogued as rs959752124, COSV54146379, COSV99624824; called by muse, mutect2, varscan2
- EVC | c.1652del p.P551Rfs*7 | Frame Shift Del (DEL) | VAF 35/156 reads (22%) | catalogued as rs1312383000; called by mutect2, pindel, varscan2
- EXOSC8 | c.698G>A p.C233Y | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53509476; called by muse, mutect2, varscan2
- F8 | c.1951C>T p.H651Y | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV64274767; called by muse, mutect2, varscan2
- FAM110B | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as COSV64066057; called by muse, mutect2, varscan2
- FAM135B | c.2167C>A p.L723I | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV99421864; called by muse, mutect2, varscan2
- FAM151A | c.351dup p.T118Hfs*5 | Frame Shift Ins (INS) | VAF 22/110 reads (20%) | catalogued as rs749953492; called by mutect2, varscan2
- FAM161B | c.1415G>A p.R472H (on ENST00000651776; = p.R409H on NM_152445.3) | Missense Mutation (SNP) | VAF 113/370 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs779578513, COSV54101707; called by muse, mutect2, varscan2
- FAM186B | c.1082C>A p.P361Q | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.087); catalogued as COSV57720624, COSV57721943; called by muse, mutect2, varscan2
- FAM193A | c.2017del p.L673Sfs*142 | Frame Shift Del (DEL) | VAF 30/101 reads (30%) | catalogued as COSV61191975; called by mutect2, pindel, varscan2
- FAM220A | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs1156709247, COSV57626647; called by muse, mutect2, varscan2
- FAM234A | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0.019); catalogued as rs761153670, COSV56995536; called by muse, mutect2, varscan2
- FAM47C | c.1787del p.P596Rfs*229 | Frame Shift Del (DEL) | VAF 31/197 reads (16%) | catalogued as COSV63724780; called by mutect2, pindel, varscan2
- FAM50B | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66654878; called by muse, mutect2, varscan2
- FAM71A | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201801823; called by muse, mutect2, varscan2
- FAM81A | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55678741; called by muse, mutect2, varscan2
- FAM9A | c.79del p.A27Pfs*70 | Frame Shift Del (DEL) | VAF 103/399 reads (26%) | catalogued as COSV101121339; called by mutect2, pindel, varscan2
- FARP1 | c.3097C>T p.R1033* | Nonsense Mutation (SNP) | VAF 96/273 reads (35%) | catalogued as rs549979587, COSV60330327; called by muse, mutect2, varscan2
- FASTKD3 | c.1918A>G p.R640G | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.253); catalogued as rs764452426, COSV99242478; called by muse, mutect2, varscan2
- FASTKD5 | c.1097C>T p.T366I | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV53906731; called by muse, mutect2, varscan2
- FAT1 | c.7207G>A p.A2403T | Missense Mutation (SNP) | VAF 19/179 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as rs770573765, COSV71674713; called by muse, mutect2, varscan2
- FAT1 | c.6866C>T p.A2289V | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs562612394, COSV71672054; called by muse, mutect2, varscan2
- FAT1 | c.6080G>A p.R2027H | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as rs745765579, COSV71674714; called by muse, mutect2, varscan2
- FAT4 | c.353C>A p.P118H | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101272212; called by muse, mutect2, varscan2
- FBN1 | c.6596G>A p.G2199D | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1566895247, COSV57320321; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBN1 | c.1077C>A p.C359* | Nonsense Mutation (SNP) | VAF 23/84 reads (27%) | catalogued as CM098641, COSV57320329; called by muse, mutect2, varscan2
- FBN2 | c.7659del p.F2554Lfs*57 | Frame Shift Del (DEL) | VAF 26/115 reads (23%) | catalogued as rs748600284, COSV99331968; called by mutect2, pindel, varscan2
- FBN3 | c.4836C>A p.H1612Q | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.852); catalogued as COSV54463917; called by muse, mutect2, varscan2
- FBXO24 | c.1639C>T p.P547S (on ENST00000241071 / NM_033506.3; = p.P585S on NM_012172.5) | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.996); catalogued as rs1252439563, COSV53826879; called by muse, mutect2, varscan2
- FBXO40 | c.1357G>T p.G453W | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); catalogued as COSV100573072, COSV57524870; called by muse, mutect2, varscan2
- FBXO41 | c.2075G>T p.R692M | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54585983; called by muse, mutect2
- FBXO48 | c.91C>T p.Q31* | Nonsense Mutation (SNP) | VAF 46/168 reads (27%) | catalogued as COSV58145667; called by muse, mutect2, varscan2
- FER1L6 | c.3718+1G>A p.X1240_splice | Splice Site (SNP) | VAF 34/134 reads (25%) | catalogued as COSV67550765; called by muse, mutect2, varscan2
- FERD3L | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51763167, COSV99284669; called by muse, mutect2, varscan2
- FERMT1 | c.1673C>T p.A558V | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs200005649, COSV54094340; called by muse, mutect2
- FEZF2 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.768); catalogued as COSV51862618; called by muse, varscan2
- FGD4 | c.1892G>T p.G631V | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV56789990, COSV99846937; called by muse, mutect2
- FGD6 | c.1591del p.S531Vfs*6 | Frame Shift Del (DEL) | VAF 43/155 reads (28%) | catalogued as rs1344831134; called by mutect2, pindel, varscan2
- FGF13 | c.665C>T p.T222I | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV59547215; called by muse, mutect2, varscan2
- FHOD3 | c.3902T>C p.L1301P (on ENST00000359247 / NM_001281739.3; = p.L1318P on NM_025135.5) | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV99940784; called by muse, mutect2, varscan2
- FICD | c.934A>G p.T312A | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV57208146; called by muse, mutect2, varscan2
- FKBP15 | c.1994del p.K665Rfs*9 | Frame Shift Del (DEL) | VAF 32/145 reads (22%) | catalogued as rs774060142; called by mutect2, pindel, varscan2
- FKBP9 | c.384del p.N129Ifs*10 | Frame Shift Del (DEL) | VAF 31/193 reads (16%) | catalogued as rs752076602; called by mutect2, pindel, varscan2
- FLII | c.533C>T p.T178M | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs140059134; called by muse, mutect2, varscan2
- FLNB | c.3428T>G p.L1143R | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55883237; called by muse, mutect2, varscan2
- FLT4 | c.784G>A p.V262I | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.557); catalogued as rs1427222919, COSV56112180; called by muse, mutect2, varscan2
- FLVCR2 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 57/184 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs974055927, COSV53162925; called by muse, mutect2, varscan2
- FMN2 | c.5104T>C p.S1702P | Missense Mutation (SNP) | VAF 59/209 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as COSV60435272; called by muse, mutect2, varscan2
- FMNL3 | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs202178648; called by muse, mutect2, varscan2
- FOLH1 | c.1823C>T p.A608V | Missense Mutation (SNP) | VAF 98/308 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV57050956; called by muse, mutect2, varscan2
- FOXA1 | c.811C>A p.Q271K | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51646787; called by muse, mutect2, varscan2
- FOXB2 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); catalogued as COSV65023273; called by muse, mutect2, varscan2
- FRAS1 | c.1051T>C p.Y351H | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as COSV53620017; called by muse, mutect2, varscan2
- FREM2 | c.4174G>A p.D1392N | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs917796927, COSV54841540; called by muse, mutect2, varscan2
- FREM2 | c.5033T>C p.M1678T | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV54841550; called by muse, mutect2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 21/66 reads (32%) | catalogued as rs752538869; called by mutect2, pindel, varscan2
- FRMPD3 | c.2102C>T p.A701V | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV52192483; called by muse, mutect2, varscan2
- FRMPD3 | c.4073G>A p.R1358K | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV52188836; called by muse, mutect2, varscan2
- FRS3 | c.1436C>T p.T479I | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV52487374; called by muse, mutect2, varscan2
- FURIN | c.596C>G p.A199G | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51577512; called by muse, mutect2, varscan2
- FYB1 | c.972dup p.P325Afs*43 | Frame Shift Ins (INS) | VAF 52/166 reads (31%) | catalogued as rs748874978; called by mutect2, varscan2
- GABRA1 | c.661C>A p.L221I | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.419); catalogued as COSV50108186, COSV50114276; called by muse, mutect2, varscan2
- GABRA6 | c.735A>G p.I245M | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50883918; called by muse, varscan2
- GAD1 | c.83C>T p.T28M | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.143); catalogued as COSV60152858; called by muse, mutect2, varscan2
- GAS2L1 | c.739C>T p.R247W | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375162998; called by muse, mutect2, varscan2
- GASK1B | c.755del p.G252Afs*23 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | catalogued as rs762957217; called by mutect2, pindel
- GATA5 | c.656T>C p.M219T | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs375617512; called by muse, mutect2, varscan2
- GATD1 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV60592697; called by muse, mutect2, varscan2
- GATM | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67540620; called by muse, mutect2, varscan2
- GCA | c.568+1G>A p.X190_splice | Splice Site (SNP) | VAF 20/71 reads (28%) | catalogued as COSV52025808, COSV99280484; called by muse, mutect2, varscan2
- GCDH | c.957-1G>T p.X319_splice | Splice Site (SNP) | VAF 48/129 reads (37%) | catalogued as COSV99535821; called by muse, mutect2, varscan2
- GCNA | c.1411C>T p.R471C | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs767793682, COSV65465978; called by muse, mutect2, varscan2
- GCNT1 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 53/184 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV65057969; called by muse, mutect2, varscan2
- GDF1 | c.1012G>A p.V338M | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1353039336, COSV53197790; called by muse, mutect2, varscan2
- GGCT | c.403C>A p.P135T | Missense Mutation (SNP) | VAF 112/400 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.931); catalogued as COSV50040913; called by muse, mutect2, varscan2
- GIGYF1 | c.1891C>A p.P631T | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV51943375; called by muse, mutect2, varscan2
- GIGYF1 | c.331del p.L111Wfs*234 | Frame Shift Del (DEL) | VAF 44/114 reads (39%) | catalogued as rs763147690; called by mutect2, varscan2
- GIMAP1 | c.314A>G p.Y105C | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV56188651; called by muse, mutect2, varscan2
- GIPC3 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.741); catalogued as COSV59259720; called by muse, mutect2, varscan2
- GIT2 | c.2102G>A p.R701H (on ENST00000355312 / NM_057169.5; = p.R623H on NM_014776.5) | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as rs753666949, COSV58079427; called by muse, mutect2, varscan2
- GJC2 | c.839T>C p.L280P | Missense Mutation (SNP) | VAF 68/175 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64512968; called by muse, mutect2, varscan2
- GLIS3 | c.2133G>A p.M711I | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as COSV100173438, COSV60930925; called by muse, mutect2, varscan2
- GLIS3 | c.1149G>A p.W383* | Nonsense Mutation (SNP) | VAF 54/156 reads (35%) | catalogued as COSV60930936; called by muse, mutect2, varscan2
- GLMP | c.119A>G p.Q40R | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV55295732; called by muse, mutect2, varscan2
- GMPS | c.922A>G p.T308A | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV55810080; called by muse, varscan2
- GNAI2 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs782148570, COSV56494382; called by muse, mutect2, varscan2
- GNL3L | c.1486C>T p.H496Y | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs748605963, COSV60576068; called by muse, mutect2, varscan2
- GNS | c.566A>G p.N189S | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50695082; called by muse, mutect2, varscan2
- GOLGB1 | c.4688A>T p.Q1563L | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61466997, COSV61472536; called by muse, mutect2, varscan2
- GOLPH3 | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 39/237 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.214); catalogued as rs773095936, COSV54060113; called by muse, mutect2, varscan2
- GORASP1 | c.351T>G p.D117E | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.03); catalogued as COSV56532583; called by muse, mutect2, varscan2
- GP5 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs1201754296, COSV55465737; called by muse, mutect2, varscan2
- GPANK1 | c.800dup p.W268Lfs*12 | Frame Shift Ins (INS) | VAF 30/152 reads (20%) | catalogued as rs765697080; called by mutect2, varscan2
- GPAT2 | c.2296G>A p.A766T | Missense Mutation (SNP) | VAF 173/562 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV64003572; called by muse, mutect2, varscan2
- GPBP1 | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 88/335 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.583); catalogued as rs753647050, COSV53310962; called by muse, mutect2, varscan2
- GPC1 | c.764A>G p.Y255C | Missense Mutation (SNP) | VAF 72/192 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99882764; called by muse, mutect2, varscan2
- GPD2 | c.2165G>A p.R722H | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1363695386, COSV60093696; called by muse, mutect2, varscan2
- GPR162 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.731); catalogued as COSV50592226; called by muse, mutect2, varscan2
- GPR179 | c.2506G>A p.A836T (on ENST00000621958; = p.A835T on NM_001004334.4) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.031); catalogued as rs769049312; called by muse, mutect2
- GPR26 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 54/175 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52934593; called by muse, mutect2, varscan2
- GPRASP2 | c.1340C>T p.A447V | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as COSV59991694; called by muse, mutect2, varscan2
- GRAMD1A | c.788G>A p.S263N | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.827); catalogued as COSV58767503; called by muse, mutect2, varscan2
- GRID1 | c.2647C>T p.L883F | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as rs569741039, COSV60035039; called by muse, mutect2, varscan2
- GRIN1 | c.2372C>T p.T791M | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.896); catalogued as COSV59293875; called by muse, mutect2, varscan2
- GRIN1 | c.2759G>A p.R920H | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.52); catalogued as COSV59297012; called by muse, mutect2, varscan2
- GRIN2A | c.4355G>A p.R1452H | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.998); catalogued as rs774039446, COSV58020621; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRIN2D | c.1190C>G p.T397R | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.046); catalogued as COSV54379967, COSV54381162; called by muse, mutect2, varscan2
- GRIN3A | c.406A>G p.N136D | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV62455138; called by muse, mutect2, varscan2
- GRK1 | c.589G>T p.G197W | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59553231; called by muse, mutect2, varscan2
- GRK3 | c.1961C>T p.A654V | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.666); catalogued as rs932052301, COSV60797191; called by muse, mutect2, varscan2
- GRK7 | c.466G>T p.A156S | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV53823520, COSV99380066; called by muse, mutect2, varscan2
- GRM2 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV56585536; called by muse, mutect2, varscan2
- GRPEL1 | c.580G>T p.V194F | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53827504; called by muse, mutect2, varscan2
- GSC | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53077298; called by muse, mutect2, varscan2
- GSG1 | c.310C>T p.R104W (on ENST00000651961 / NM_001080555.4; = p.R91W on NM_031289.5) | Missense Mutation (SNP) | VAF 79/175 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs536441717, COSV60971556; called by muse, mutect2, varscan2
- GYPA | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 61/134 reads (46%) | SIFT tolerated (0.95); PolyPhen benign (0.019); catalogued as COSV51629562; called by muse, mutect2, varscan2
- GYPB | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 72/626 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.184); catalogued as COSV99301487; called by muse, mutect2, varscan2
- GZMM | c.753G>T p.K251N | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV52742420; called by muse, mutect2, varscan2
- H2AB1 | c.64C>A p.R22S | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV100371577; called by mutect2, varscan2
- H2AW | c.222_224del p.N74del | In Frame Del (DEL) | VAF 42/197 reads (21%) | catalogued as rs758247238; called by pindel, varscan2
- H2BC8 | c.25_27del p.P9del | In Frame Del (DEL) | VAF 32/149 reads (21%) | catalogued as rs1243291810; called by mutect2, pindel, varscan2
- H3C1 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 62/178 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs1029963018, COSV55119710; called by muse, mutect2, varscan2
- H3C6 | c.320A>G p.D107G | Missense Mutation (SNP) | VAF 21/299 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100839013; called by muse, mutect2
- HCLS1 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.055); catalogued as COSV57524876; called by muse, mutect2, varscan2
- HCN3 | c.1810G>A p.E604K | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.191); catalogued as COSV61361567; called by muse, mutect2, varscan2
- HDAC9 | c.533C>T p.T178M | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as rs1319365754, COSV67775983; called by muse, mutect2, varscan2
- HEATR5A | c.4925C>T p.A1642V | Missense Mutation (SNP) | VAF 62/207 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV66342124; called by muse, mutect2, varscan2
- HEATR5A | c.3326C>T p.A1109V | Missense Mutation (SNP) | VAF 17/214 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV66342129; called by muse, mutect2
- HELLS | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 72/201 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs780221772, COSV53298390; called by muse, mutect2, varscan2
- HELQ | c.1096del p.T366Pfs*7 | Frame Shift Del (DEL) | VAF 28/224 reads (13%) | catalogued as COSV55028517; called by pindel, varscan2
- HELZ2 | c.6529+1G>A p.X2177_splice (on ENST00000467148 / NM_001037335.2; = p.X1608_splice on NM_033405.3) | Splice Site (SNP) | VAF 19/54 reads (35%) | catalogued as COSV101427542; called by muse, mutect2, varscan2
- HEPHL1 | c.1556A>G p.K519R | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV100243781; called by muse, mutect2, varscan2
- HEPHL1 | c.1819A>G p.S607G | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100243782; called by muse, mutect2, varscan2
- HERC2 | c.8887G>A p.V2963M | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772742501, COSV99872431; called by muse, mutect2, varscan2
- HERC2 | c.6976C>A p.L2326M | Missense Mutation (SNP) | VAF 143/480 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); catalogued as COSV55329521; called by muse, mutect2, varscan2
- HFM1 | c.2903T>C p.L968S | Missense Mutation (SNP) | VAF 44/281 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54029898; called by muse, mutect2, varscan2
- HGD | c.1242G>T p.K414N | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV52199030; called by muse, mutect2, varscan2
- HGS | c.34C>A p.L12I | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.402); catalogued as COSV61268427; called by muse, mutect2, varscan2
- HGSNAT | c.727G>A p.V243M | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs373469974, COSV65535090; called by muse, mutect2, varscan2
- HIF1AN | c.926C>A p.P309H | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54500795; called by muse, mutect2, varscan2
- HIVEP1 | c.4094G>A p.R1365H | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376295702; called by muse, mutect2, varscan2
- HMCN1 | c.12149G>A p.R4050Q | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0.017); catalogued as rs565996021, COSV54909944; ClinVar: uncertain significance; called by muse, varscan2
- HMCN1 | c.12320C>T p.P4107L | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.342); catalogued as rs766042341, COSV54897186; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HMX3 | c.68del p.P23Hfs*100 | Frame Shift Del (DEL) | VAF 18/24 reads (75%) | catalogued as rs779589617; called by mutect2, varscan2
- HNF1A | c.1136del p.P379Lfs*5 | Frame Shift Del (DEL) | VAF 10/27 reads (37%) | catalogued as COSV57466638; called by mutect2, pindel, varscan2
- HNRNPK | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as COSV61089486; called by muse, mutect2, varscan2
- HNRNPL | c.1255C>T p.P419S | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55492738; called by muse, mutect2, varscan2
- HNRNPL | c.1010del p.P337Hfs*58 | Frame Shift Del (DEL) | VAF 20/70 reads (29%) | catalogued as rs767148651; called by mutect2, varscan2
- HOATZ | c.62dup p.L23Ifs*16 | Frame Shift Ins (INS) | VAF 18/87 reads (21%) | catalogued as rs570525399; called by mutect2, pindel, varscan2
- HOOK2 | c.1847C>A p.P616H | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53402722; called by muse, mutect2, varscan2
- HPN | c.259G>A p.G87R | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.048); catalogued as rs151248493; called by muse, mutect2, varscan2
- HPS4 | c.1537G>A p.A513T | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV61103967; called by muse, mutect2, varscan2
- HPSE2 | c.961A>G p.M321V | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as rs1254320485, COSV65192097; called by muse, varscan2
- HRH4 | c.1009T>A p.S337T | Missense Mutation (SNP) | VAF 135/375 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.055); catalogued as COSV56928524; called by muse, mutect2, varscan2
- HROB | c.1245G>T p.E415D | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV55369925; called by muse, mutect2, varscan2
- HS1BP3 | c.702G>T p.E234D | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV58313516; called by muse, mutect2, varscan2
- HSD3B7 | c.591A>C p.E197D | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.859); catalogued as COSV52680810; called by muse, mutect2, varscan2
- HTR2B | c.1004T>G p.L335R | Missense Mutation (SNP) | VAF 79/229 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV51450093; called by muse, mutect2, varscan2
- HUNK | c.395C>T p.T132M | Missense Mutation (SNP) | VAF 55/146 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761716649, COSV54230123; called by muse, mutect2, varscan2
- ICAM3 | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.579); catalogued as COSV50329294; called by muse, mutect2, varscan2
- ICAM5 | c.647C>T p.S216L | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55747683; called by muse, mutect2, varscan2
- IFFO1 | c.1089del p.R364Gfs*47 (on ENST00000396840 / NM_001330324.2; = p.R367Gfs*47 on NM_080730.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 24/66 reads (36%) | catalogued as rs750779916, COSV60737300; called by mutect2, pindel, varscan2
- IFT57 | c.991C>T p.R331* | Nonsense Mutation (SNP) | VAF 32/106 reads (30%) | catalogued as rs1017459667, COSV52708830; called by muse, mutect2, varscan2
- IFT80 | c.938C>T p.T313M | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.146); catalogued as rs753478409, COSV58449328; ClinVar: uncertain significance; called by muse, varscan2
- IGF2R | c.3949del p.D1317Tfs*27 | Frame Shift Del (DEL) | VAF 43/105 reads (41%) | catalogued as rs760021495; called by mutect2, varscan2
- IGF2R | c.6104G>A p.G2035E | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63629997; called by muse, mutect2, varscan2
- IGFLR1 | c.173A>G p.E58G | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV53075450; called by muse, mutect2, varscan2
- IGFN1 | c.2512G>A p.A838T (on ENST00000295591 / NM_001367841.1; = p.A3295T on NM_001164586.2) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55175260; called by muse, mutect2, varscan2
- IGKJ1 | c.3G>A p.*1= | Missense Mutation (SNP) | VAF 29/99 reads (29%) | catalogued as rs373905902; called by muse, mutect2, varscan2
- IGKV2-24 | c.170A>G p.Y57C | Missense Mutation (SNP) | VAF 120/400 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as rs762363282; called by muse, mutect2, varscan2
- IGLV8-61 | c.277C>A p.L93I | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV66503347; called by muse, mutect2, varscan2
- IGSF9 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs781724050, COSV63640550; called by muse, mutect2, varscan2
- IGSF9B | c.3557G>A p.R1186H | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.749); catalogued as COSV58069146; called by muse, mutect2, varscan2
- IHH | c.167T>C p.V56A | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV55393457; called by muse, mutect2
- IL12RB2 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 56/196 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52024168; called by muse, mutect2, varscan2
- IL13RA2 | c.317A>G p.H106R | Missense Mutation (SNP) | VAF 97/330 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs1036739144, COSV54565692; called by muse, mutect2, varscan2
- IL17RB | c.740C>T p.T247M | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs541664266, COSV55473291; called by muse, mutect2, varscan2
- IL18RAP | c.919A>G p.S307G | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as COSV99961872; called by muse, mutect2, varscan2
- IL22RA1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 44/167 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54629128; called by muse, mutect2
- ILDR2 | c.1268C>T p.P423L | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.216); catalogued as rs752331552, COSV54832239; called by muse, mutect2, varscan2
- IMPG1 | c.1982G>A p.R661H | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.986); catalogued as rs200128845, COSV64058955; called by muse, mutect2, varscan2
- INO80 | c.2189A>G p.N730S | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.581); catalogued as COSV62739162; called by muse, mutect2, varscan2
- INPP5D | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 56/200 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV64037911; called by muse, mutect2, varscan2
- INPPL1 | c.3026T>C p.V1009A | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV99996086; called by mutect2, varscan2
- INSRR | c.3695A>G p.N1232S | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV63874633; called by muse, mutect2, varscan2
- INSRR | c.2757del p.L920Cfs*37 | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | catalogued as rs772259106; called by mutect2, pindel, varscan2
- INTS11 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 62/197 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.201); catalogued as rs764130667, COSV60088963; called by muse, mutect2, varscan2
- INTS7 | c.2539A>T p.I847F | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65344505; called by muse, mutect2, varscan2
- INTS7 | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 56/265 reads (21%) | SIFT tolerated (1); PolyPhen possibly damaging (0.905); catalogued as COSV65344508; called by muse, mutect2, varscan2
- IQSEC2 | c.2513G>A p.R838Q (on ENST00000642864 / NM_001111125.3; = p.R633Q on NM_015075.2) | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64726289; called by muse, mutect2, varscan2
- IQSEC3 | c.2452G>A p.D818N (on ENST00000538872 / NM_001170738.2; = p.D515N on NM_015232.1) | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.236); catalogued as rs1462809067, COSV58286303; called by muse, mutect2, varscan2
- IRAK4 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs764106350, COSV71210312; called by muse, mutect2, varscan2
- IRGC | c.487T>C p.F163L | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.432); catalogued as COSV54984816; called by muse, mutect2
- IRGQ | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60670747; called by muse, mutect2, varscan2
- IRS1 | c.1666C>T p.P556S | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.471); catalogued as COSV59337394; called by muse, mutect2, varscan2
- IRS2 | c.3523G>A p.A1175T | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV65479298, COSV65480680; called by muse, mutect2, varscan2
- ISLR2 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.129); catalogued as rs146206854; called by muse, mutect2, varscan2
- ISLR2 | c.1397G>A p.R466Q | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.011); catalogued as COSV100679452, COSV62302498; called by muse, mutect2, varscan2
- ITGA1 | c.721G>A p.V241I | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV50885187; called by muse, mutect2, varscan2
- ITGAE | c.1399G>A p.V467M | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.421); catalogued as rs754058055, COSV99560760; called by muse, mutect2, varscan2
- ITGAE | c.582G>C p.E194D | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs1040691175, COSV99560766; called by muse, mutect2, varscan2
- ITGB4 | c.3910del p.A1304Pfs*140 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | catalogued as COSV52322796; called by mutect2, pindel
- ITGB8 | c.27dup p.T10Yfs*34 | Frame Shift Ins (INS) | VAF 16/65 reads (25%) | catalogued as rs760028800; called by mutect2, varscan2
- ITIH2 | c.535T>G p.F179V | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100623247; called by muse, mutect2, varscan2
- ITIH5 | c.1229C>T p.T410M | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs770290121, COSV53662739, COSV53668432; called by muse, mutect2, varscan2
- ITPKC | c.1919G>A p.G640D | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54575494; called by muse, mutect2, varscan2
- ITPR2 | c.4839G>T p.L1613F | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); catalogued as COSV67270996; called by muse, mutect2, varscan2
- ITSN2 | c.1306C>T p.R436* | Nonsense Mutation (SNP) | VAF 107/344 reads (31%) | catalogued as rs766072107, COSV61949085; called by muse, mutect2, varscan2
- JCAD | c.3037A>G p.K1013E | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as COSV64760236; called by muse, mutect2, varscan2
- JCAD | c.887C>A p.P296Q | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV64760245; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); catalogued as COSV52963123; called by muse, mutect2, varscan2
- JMJD8 | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs571730014, COSV50198833; called by muse, mutect2, varscan2
- JUP | c.1669G>T p.E557* | Nonsense Mutation (SNP) | VAF 26/58 reads (45%) | catalogued as COSV60278592; called by muse, mutect2, varscan2
- KAZN | c.1343C>T p.A448V | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); catalogued as rs369808373; called by muse, mutect2, varscan2
- KBTBD7 | c.337A>G p.T113A | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.856); catalogued as rs768665690, COSV65266688; called by muse, mutect2, varscan2
- KCNA3 | c.1244C>T p.A415V | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63901969; called by muse, mutect2, varscan2
- KCNA5 | c.307G>A p.G103S | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV52906733; called by muse, mutect2, varscan2
- KCNC3 | c.2114G>A p.R705Q | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.885); catalogued as rs754380441, COSV65387856; called by muse, mutect2, varscan2
- KCNF1 | c.1250G>A p.R417H | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.379); catalogued as COSV54462706; called by muse, mutect2, varscan2
- KCNH2 | c.3430del p.A1144Pfs*111 | Frame Shift Del (DEL) | VAF 38/128 reads (30%) | catalogued as CM085497; called by mutect2, pindel, varscan2
- KCNH3 | c.776G>A p.G259D | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV99235033; called by muse, mutect2, varscan2
- KCNJ1 | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV60662076; called by muse, mutect2, varscan2
- KCNJ12 | c.509G>A p.C170Y | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV59168421; called by muse, mutect2, varscan2
- KCNK13 | c.335-2A>G p.X112_splice | Splice Site (SNP) | VAF 62/184 reads (34%) | catalogued as COSV56414159; called by muse, mutect2
- KCNMB4 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 96/279 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1289045846, COSV50690679, COSV50690910; called by muse, mutect2, varscan2
- KCNS2 | c.487G>A p.G163R | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs145156738; called by muse, mutect2, varscan2
- KCNT1 | c.1162C>A p.L388M (on ENST00000488444; = p.L407M on NM_020822.3) | Missense Mutation (SNP) | VAF 59/153 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV99705468, COSV99707060; called by muse, mutect2, varscan2
- KCNV1 | c.1111A>G p.I371V | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV52086765; called by muse, mutect2, varscan2
- KCTD20 | c.269A>G p.N90S | Missense Mutation (SNP) | VAF 52/173 reads (30%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as COSV54803618; called by muse, mutect2, varscan2
- KDF1 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.23); catalogued as COSV57671637; called by muse, mutect2, varscan2
- KDM4C | c.1148C>A p.P383H | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV67187838; called by muse, mutect2, varscan2
- KDM5B | c.4534T>C p.W1512R | Missense Mutation (SNP) | VAF 10/135 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99350376; called by muse, mutect2
- KIAA0319L | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV57846931; called by muse, mutect2, varscan2
- KIAA1109 | c.1992G>A p.W664* | Nonsense Mutation (SNP) | VAF 69/240 reads (29%) | catalogued as rs1364272714, COSV52678299; called by muse, mutect2, varscan2
- KIAA1109 | c.12344G>A p.G4115E | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.07); catalogued as COSV52678318; called by muse, mutect2, varscan2
- KIAA1522 | c.2927del p.P976Hfs*70 (on ENST00000373480 / NM_001198972.2; = p.P1035Hfs*70 on NM_020888.3) | Frame Shift Del (DEL) | VAF 71/238 reads (30%) | catalogued as COSV99615233; called by mutect2, pindel, varscan2
- KIAA1549L | c.521T>C p.V174A (on ENST00000321505; = p.V471A on NM_012194.3) | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); catalogued as COSV55775730; called by muse, mutect2
- KIAA1614 | c.149del p.P50Qfs*15 | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | catalogued as rs771572430; called by mutect2, pindel, varscan2
- KIAA1958 | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as rs768342901, COSV61724812; called by muse, mutect2, varscan2
- KIF1B | c.2648G>A p.R883Q (on ENST00000377086 / NM_001365952.1; = p.R837Q on NM_015074.3) | Missense Mutation (SNP) | VAF 86/295 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV55810028, COSV55813450; called by muse, mutect2, varscan2
- KIF1B | c.5441C>T p.S1814L (on ENST00000377086 / NM_001365952.1; = p.S1768L on NM_015074.3) | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs761319935, COSV55810547; called by muse, mutect2, varscan2
- KIF26A | c.3031C>T p.R1011W | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs1373498323, COSV100181010; called by muse, mutect2, varscan2
- KIF26A | c.3451G>A p.G1151S | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59467633; called by muse, mutect2, varscan2
- KIF26A | c.5288G>A p.R1763H | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs759984495, COSV59467641; called by muse, mutect2, varscan2
- KIFC1 | c.1793C>T p.T598M | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1283356105, COSV100996041; called by muse, mutect2, varscan2
- KIRREL2 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761189830, COSV52877346; called by muse, mutect2, varscan2
- KLC3 | c.1021C>A p.L341M | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67268742; called by muse, mutect2, varscan2
- KLF13 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56147802; called by muse, mutect2, varscan2
- KLHDC9 | c.387del p.A130Pfs*37 | Frame Shift Del (DEL) | VAF 5/25 reads (20%) | catalogued as rs761803466; called by mutect2, pindel, varscan2
- KLHL30 | c.1583A>G p.D528G | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100014186; called by muse, mutect2, varscan2
- KLHL4 | c.1456G>A p.G486S | Missense Mutation (SNP) | VAF 82/276 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770069239, COSV64139273, COSV64146543; called by muse, mutect2, varscan2
- KLHL40 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV99825423; called by muse, mutect2, varscan2
- KLK11 | c.293C>T p.P98L (on ENST00000594768 / NM_144947.3; = p.P66L on NM_006853.3) | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as rs200477811, COSV51577530, COSV99141877; called by muse, mutect2, varscan2
- KLK13 | c.365A>G p.D122G | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.974); catalogued as COSV50067193; called by muse, mutect2, varscan2
- KMT2B | c.3904C>T p.R1302C | Missense Mutation (SNP) | VAF 56/179 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1255849701, COSV99718959; called by muse, mutect2, varscan2
- KMT2B | c.7612del p.A2538Pfs*76 | Frame Shift Del (DEL) | VAF 23/75 reads (31%) | catalogued as rs35021476; called by mutect2, pindel, varscan2
- KMT2C | c.1412G>T p.G471V | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.462); catalogued as COSV51454082; called by muse, mutect2, varscan2
- KMT2D | c.8624C>T p.A2875V | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV56453003; called by muse, mutect2, varscan2
- KRT17 | c.65del p.G22Afs*93 | Frame Shift Del (DEL) | VAF 10/33 reads (30%) | catalogued as rs753167272; called by mutect2, pindel
- KRT31 | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.987); catalogued as rs760386378, COSV52434745; called by muse, mutect2, varscan2
- KRT31 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.713); catalogued as rs200375490; called by muse, mutect2, varscan2
- KRT71 | c.1295A>G p.Y432C | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57291257; called by muse, mutect2, varscan2
- KRTAP1-5 | c.245A>G p.Q82R | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.9); PolyPhen benign (0.063); catalogued as COSV62624366; called by muse, mutect2, varscan2
- KRTAP10-6 | c.669del p.C224Afs*157 | Frame Shift Del (DEL) | VAF 89/352 reads (25%) | catalogued as rs1555926661; called by mutect2, pindel, varscan2
- KRTAP4-3 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 76/220 reads (35%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.594); catalogued as rs763394569, COSV66940753; called by muse, mutect2, varscan2
- L1TD1 | c.59A>G p.E20G | Missense Mutation (SNP) | VAF 67/238 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as rs1238241450, COSV100776555; called by muse, mutect2, varscan2
- L1TD1 | c.1550A>G p.D517G | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV63133620; called by muse, mutect2, varscan2
- L3MBTL3 | c.1178T>C p.V393A | Missense Mutation (SNP) | VAF 55/198 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100695905; called by muse, mutect2, varscan2
- LACC1 | c.1040G>T p.R347M | Missense Mutation (SNP) | VAF 57/240 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as COSV57829289; called by muse, mutect2, varscan2
- LAMA3 | c.4973del p.P1658Lfs*91 | Frame Shift Del (DEL) | VAF 29/85 reads (34%) | catalogued as rs759440110; called by mutect2, pindel, varscan2
- LAMA5 | c.10529T>C p.V3510A | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV53362631; called by muse, mutect2, varscan2
- LANCL2 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs776342559, COSV54650108; called by muse, mutect2, varscan2
- LARP4B | c.1703G>A p.S568N | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60221949; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 55/193 reads (28%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LCE3D | c.128del p.G43Afs*12 | Frame Shift Del (DEL) | VAF 53/179 reads (30%) | catalogued as rs1557783827, CM140039; called by mutect2, pindel, varscan2
1,733 further variants in this file (1,112 protein-altering or splice-affecting, 571 silent, 50 other) are not listed here.
